Somatic mutation profile of tumor specimen TCGA-AZ-6607-01A (aliquot TCGA-AZ-6607-01A-11D-1835-10) from TCGA case TCGA-AZ-6607, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.7 years (25,448 days).
Specimen TCGA-AZ-6607-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d00b7ab-8234-40f7-ae82-a69451df18ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6607-11A (Solid Tissue Normal), aliquot TCGA-AZ-6607-11A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/675a1a2d-ac3c-41aa-80bf-7aababa3e131

The open-access MAF lists 78 somatic variants for this specimen: 57 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 18, Nonsense Mutation 3, Intron 2, 3'UTR 1, Translation Start Site 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 100/212 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC11 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761021001, COSV62321722; called by muse, mutect2, varscan2
- ACOX1 | c.1728+2T>G p.X576_splice | Splice Site (SNP) | VAF 25/72 reads (35%) | catalogued as COSV53133423; called by muse, mutect2, varscan2
- ADPRH | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99053037; called by muse, mutect2, varscan2
- AICDA | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as COSV57564592; called by muse, mutect2, varscan2
- ANKIB1 | c.1662A>T p.K554N | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99729999; called by muse, mutect2, varscan2
- APOB | c.10190C>T p.T3397I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99268297; called by muse, mutect2, varscan2
- ATP9A | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs756569236, COSV58766993; called by muse, mutect2, varscan2
- B4GALT6 | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52703647; called by muse, mutect2, varscan2
- C1D | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV63413278; called by muse, mutect2, varscan2
- CD163 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757801947, COSV63130962; called by muse, mutect2, varscan2
- CDH23 | c.5476C>T p.R1826W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs753656026, COSV56450301; called by mutect2, varscan2
- CRYBG3 | c.6046G>A p.A2016T | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs373912145; called by muse, mutect2, varscan2
- CSE1L | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53702113; called by muse, mutect2, varscan2
- CYP4A22 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as rs1249248656, COSV53740513; called by muse, mutect2, varscan2
- DOK1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs370948984; called by muse, mutect2, varscan2
- DSCAML1 | c.4189G>A p.D1397N (on ENST00000321322; = p.D1337N on NM_020693.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100357339; called by muse, mutect2
- FRMD4A | c.1120T>C p.S374P | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52724028; called by muse, mutect2, varscan2
- GH2 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.244); catalogued as rs199964660, COSV60426925; called by muse, mutect2
- GNG4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/81 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV63999468; called by muse, mutect2, varscan2
- HBS1L | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as CM1311869, COSV63200929; called by muse, mutect2, varscan2
- HYDIN | c.315T>G p.I105M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55486612; called by muse, mutect2, varscan2
- IGF2BP1 | c.1613A>T p.K538I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51731700; called by muse, mutect2, varscan2
- ITGAD | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774788385, COSV101210232, COSV66757241; called by muse, mutect2, varscan2
- ITGB2 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV56608459; called by mutect2, varscan2
- MCM3AP | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs139188881; called by muse, mutect2, varscan2
- MIGA2 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as rs776480813, COSV52976170; called by muse, mutect2, varscan2
- MMP17 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144538442; called by muse, mutect2, varscan2
- MUC16 | c.31106G>T p.S10369I | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); catalogued as COSV101201841, COSV67455029; called by muse, mutect2
- MYO18A | c.4300C>T p.R1434* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV62866791; called by muse, mutect2, varscan2
- NAV1 | c.3845A>G p.E1282G | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs747212808, COSV99819767; called by mutect2, varscan2
- NDN | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV59358632; called by muse, mutect2, varscan2
- NEB | c.11429A>G p.K3810R | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV51420130; called by muse, mutect2, varscan2
- OR6C70 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs868102243, COSV59244889; called by muse, mutect2, varscan2
- OSMR | c.2269G>T p.V757F | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV57085671; called by muse, mutect2, varscan2
- PCOLCE | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53826318; called by muse, mutect2, varscan2
- PDCD6IP | c.1049A>C p.K350T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.242); catalogued as COSV100219196; called by muse, mutect2
- PDZD2 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56859136; called by muse, mutect2, varscan2
- RBM28 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.888); catalogued as rs548440684, COSV56164163; called by muse, mutect2, varscan2
- RBMXL2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as rs373944375; called by muse, mutect2, varscan2
- RCAN1 | c.414A>T p.L138F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58250078; called by muse, mutect2, varscan2
- REXO5 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV99759513; called by muse, mutect2, varscan2
- S1PR3 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100822638; called by muse, mutect2, varscan2
- SNRNP35 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs977160224, COSV63472004; called by muse, mutect2, varscan2
- SOGA3 | c.1917C>A p.S639R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV100847082, COSV64106411; called by muse, varscan2
- SYNPO2 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61111415; called by muse, mutect2, varscan2
- TRIB2 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs376273712; called by muse, mutect2, varscan2
- VAMP3 | c.57A>C p.Q19H | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV50012578; called by muse, mutect2, varscan2
- VPS41 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV59648999; called by muse, mutect2, varscan2
- ZBTB46 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 27/96 reads (28%) | catalogued as rs745838266, COSV55510441; called by muse, mutect2, varscan2
- ZNF420 | c.1832G>A p.G611D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58494272; called by muse, mutect2, varscan2
- ZNF462 | c.1975C>A p.Q659K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV52939228; called by muse, mutect2, varscan2
- ARID1A | c.1951A>T p.M651L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by mutect2, varscan2
- IGHG2 | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PAX1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN10A | c.2716del p.E906Rfs*2 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- ALX4 | c.744C>T p.A248= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100241328; called by muse, mutect2, varscan2
- BTNL3 | c.1320G>A p.L440= | Silent (SNP) | VAF 79/149 reads (53%) | catalogued as COSV61564935; called by muse, mutect2, varscan2
- BTNL8 | c.1152A>G p.G384= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV99180588; called by muse, mutect2
- CDKL5 | c.2928G>A p.P976= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs140944590, COSV66106625; ClinVar: likely benign; called by mutect2, varscan2
- GPR50 | c.882C>T p.Y294= | Silent (SNP) | VAF 45/55 reads (82%) | catalogued as rs758407918, COSV54439367, COSV54439845; called by muse, mutect2, varscan2
- HOXC12 | c.666G>A p.S222= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs1160088665, COSV54534767; called by muse, mutect2, varscan2
- KCNT2 | c.1110A>T p.L370= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV54081471, COSV99653150; called by muse, mutect2, varscan2
- KRTAP1-1 | c.96C>A p.T32= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs1259510748, COSV60398374; called by muse, mutect2, varscan2
- LPAR6 | c.513T>C p.N171= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV57308995; called by muse, mutect2, varscan2
- MAGEF1 | c.99G>A p.S33= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100511012, COSV58633794; called by muse, mutect2, varscan2
- NAV1 | c.2559A>T p.S853= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV55218058; called by muse, mutect2, varscan2
- NPC1L1 | c.249C>T p.T83= | Silent (SNP) | VAF 56/121 reads (46%) | catalogued as rs139883595; called by muse, mutect2, varscan2
- OR4C6 | c.360C>T p.R120= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV100051876; called by muse, mutect2, varscan2
- PXN | c.477G>A p.P159= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs374969563; called by muse, mutect2, varscan2
- RAX2 | c.129G>A p.E43= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100349789; called by muse, mutect2
- STPG2 | c.525T>C p.N175= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV54799452; called by muse, mutect2, varscan2
- TMPRSS9 | c.465C>T p.H155= (on ENST00000648592; = p.H121= on NM_182973.2) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1354101355, COSV60227728; called by muse, mutect2, varscan2
- TUBGCP2 | c.2514C>T p.A838= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1437021463, COSV53305396; called by muse, mutect2
- PIGK | c.987-6967C>T | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as rs774786837; called by muse, mutect2, varscan2
- SLC35A3 | c.*156A>T | 3'UTR (SNP) | VAF 7/43 reads (16%) | catalogued as COSV64515969; called by muse, mutect2, varscan2
- TTN | c.10361-4980T>C | Intron (SNP) | VAF 13/194 reads (7%) | catalogued as rs1278398453, COSV100631661; called by muse, mutect2
